Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NJ-01A (Primary Tumor).

DIAGNOSIS:

A. Liver and gallbladder, right lobe, wedge resection and
cholecystectomy: Multifocal moderately differentiated
hepatocellular carcinoma forming 2 separate nodules (4.4 x 4.2 x 3.0
cm and 0.6 x 0.6 x 0.6 cm). The largest nodule is located 3.9 cm
from the closest surgical margin. No definitive vascular invasion
identified. All margins of resection are negative for tumor. The
non-neoplastic liver shows mildly active (grade 1 of 3)
steatohepatitis with mild portal fibrosis (stage 1 of 4). The
gallbladder shows chronic cholecystitis. A single pericystic lymph
node is negative for tumor.

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

9/12/24/12

Source: NCI Genomic Data Commons file 01f615ea-a3d7-4540-b4b4-c2a4404d039e (TCGA-DD-A4NJ.36C3150D-343E-4B3F-A5D7-1AE978246648.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).